Gene-level copy-number profile of tumor specimen TCGA-LK-A4O0-01A from TCGA case TCGA-LK-A4O0, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 81.6 years (29,798 days).
Specimen TCGA-LK-A4O0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.12004407-d00f-4d5b-8388-d67989050af8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LK-A4O0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d186f430-b9ad-49b8-9ede-497e73f2f8f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 106; copy number 1: 7; copy number 2: 30,217; copy number 3: 3,377; copy number 4: 25,916; copy number 5: 191.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LK-A4O0-01A-11D-A34B-01): tumor purity 0.49, ploidy 1.49, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–23,438,700, 20 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr12:39,755,025–40,106,089, 1 gene (within-gene range 0–2): SLC2A13.
- chr12:40,068,243–40,224,915, 4 genes: RPL30P13, LINC02555, LINC02471, LRRK2-DT.
- chr16:86,081,409–86,349,688, 9 genes: AC135012.1, AC135012.2, AC135012.3, LINC01082, LINC01081, Y_RNA, LINC02135, LINC00917, AC092327.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 191 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–3,704,153, 68 genes, copy number 5 (broad region; genes not listed).
- chr2:6,819,463–10,427,617, 70 genes, copy number 5 (broad region; genes not listed).
- chr2:11,102,142–15,680,484, 53 genes, copy number 5: RPL6P4, AC062028.1, C2orf50, SLC66A3, ROCK2, RNU6-1081P, AIDAP1, PPIAP60, AC099344.1, LINC00570, AC099344.2, AC099344.3, E2F6, GREB1, RNA5SP84, MIR4429, RNU2-13P, 5S_rRNA, RN7SL674P, NTSR2, CDK8P1, AC106875.2, LPIN1, AC106875.1, AC012456.1, AC012456.2, MIR548S, MIR3681HG, MIR4262, SNORD18, MIR3681, RNU6-843P, AC096559.1, AC009486.2, AC009486.1, TRIB2, MIR3125, AC064875.1, AC093912.1, AC073062.1, LINC00276, AC016730.1, RNU6-1288P, Metazoa_SRP, AC011897.1, LRATD1, AC068286.2, AC068286.1, NBAS, RPS26P18, AC008278.2, DDX1, AC008278.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
